TCGA case TCGA-DX-A3UF — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5b9d27a3-7483-4118-a719-a164800ba957

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Dead; Days to death: 2,599 days (7.1 years).

Diagnoses (4)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 65.7 years (23,993 days); Year of diagnosis: 2007; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Sites of involvement: Inferior Vena Cava; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 2.9; Tumor length measurement: 3.7; Tumor width measurement: 2.9.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 1.9; Tumor length measurement: 2.9; Tumor width measurement: 2.2.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 1; Tumor length measurement: 2; Tumor width measurement: 1.5.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3; Tumor length measurement: 5; Tumor width measurement: 4.
2. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS), site: Retroperitoneum. Age at diagnosis: 68.3 years (24,957 days); Days to diagnosis: 964 days (2.6 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3.2; Tumor width measurement: 3.6.
3. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Retroperitoneum. Age at diagnosis: 70.6 years (25,785 days); Days to diagnosis: 1,792 days (4.9 years); Prior treatment: Yes.
4. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS), site: Retroperitoneum. Age at diagnosis: 71.0 years (25,922 days); Days to diagnosis: 1,929 days (5.3 years); Prior treatment: Yes; Tumor focality: Multifocal.

Follow-up (9 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 2.
- Day 964 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Retroperitoneum; Days to progression: 964 days (2.6 years).
- Day 964 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 964 days (2.6 years).
- Day 1,792 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Retroperitoneum; Days to progression: 1,792 days (4.9 years).
- Day 1,929 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 1,929 days (5.3 years).
- Days to follow up: 1,952 days (5.3 years); Disease response: With Tumor.
- Days to follow up: 1,974 days (5.4 years); Disease response: With Tumor.
- Days to follow up: 2,491 days (6.8 years); Disease response: With Tumor.
- Days to follow up: 2,599 days (7.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 10.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A3UF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 200 mg.
  Slide TCGA-DX-A3UF-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A3UF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A3UF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: Inferior vena cava; Margin status: Positive; Disease multifocal indicator: Yes; Discontinuous lesions count: 2.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology, Tumor sizes, Tumor size 3: Lesion pathologic length: 5; Lesion pathologic width: 4; Lesion pathologic depth: 3.
- Primary pathology, Tumor sizes, Tumor size 4: Lesion pathologic length: 2; Lesion pathologic depth: 1.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 1802; Days from index date to pharmaceutical treatment ended: 1915; Pharmaceutical therapy drug name: MORAb-004; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 1938; Days from index date to pharmaceutical treatment ended: 1945; Pharmaceutical therapy drug name: MLN8237; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,599 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,599 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 964 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A3UF-01A-11D-A306-01): tumor purity 0.88, ploidy 1.7, whole-genome doublings 0.
